Surgical pathology report (de-identified scan), TCGA case TCGA-29-1697, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1697-01A (Primary Tumor).

[page 1 of 2]
Surg Path**CLINICAL HISTORY:**

Pelvic mass.

TCGA-29-1697

GROSS EXAMINATION:

A. "Omentum", received fresh and later placed in formalin. A 14.0 x 11.2 x 2.0 cm aggregate of yellow-tan, lobulated adipose tissue is received. The tissue displays multiple confluent areas of tan-white nodules, 6.2 x 3.1 x 1.8 cm grossly consistent with omental caking. Representative sections in A1-A2.

B. "Left tube and ovary", received fresh and later placed in formalin. A 26.9 gram specimen composed of a 2.7 x 2.3 x 1.4 cm ovary and a 7.5 long fallopian tube with a diameter that ranges from 0.6 cm to 2.2 cm. The serosal surface of the ovary exhibits multiple tan-white papillary excrescences, and the paraovarian tissue is studied with multiple tan-white nodules. The fallopian is severely dilated, and exhibits a tan-white, fibrous stricture at its approximate mid point. There is a 0.5 cm in greatest dimension, tan-white nodule present on the fallopian tube near one of its end. The stricture site of the fallopian tube is sectioned to reveal intraluminal tan-white tumor and diffused fallopian tube wall thickening up to 0.3 cm. On sectioning, the ovary reveals a tan-white cystic cavity up to 0.9 cm in greatest dimension and a multinodular cut surface.

BLOCK SUMMARY:

- B1-B3- representative section of tumor in fallopian tube
- B4- representative ovary and representative normal fallopian tube
- B5- representative ovary and representative fallopian tube with paratubal nodule
- B6- representative ovary
- B7- representative paraovarian tissue with nodules

C. "Right tube and ovary", received fresh and later placed in formalin. A 55.3 gram specimen consisting of a 5.2 x 2.9 x 2.2 cm ovarian mass and a 7.5 cm long fallopian tube with a diameter that ranges from 0.3 cm to 1.1 cm. Upon sectioning, the mass has completely obliterated the ovarian architecture, and is composed of pink-tan, very friable tissue. The fallopian tube is mildly dilated and exhibits multiple tan-white implants, up to 0.7 cm in greatest dimension.

BLOCK SUMMARY:

- C1- representative sections of fallopian tube with implants
- C2-C4- representative sections of ovarian mass

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

- A. "OMENTUM" (OMENTECTOMY):

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA, CONSISTENT WITH OVARIAN PRIMARY.
SIZE OF LARGEST METASTASIS: 6.0 CM.

[page 2 of 2]
B. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY);

OVARY AND FALLOPIAN TUBE WITH POORLY DIFFERENTIATED PAPILLARY SEROUS
ADENOCARCINOMA.

TCGA-29-1697

C. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

OVARY WITH POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.

TUMOR SIZE: 5.2 CM.

FIGO GRADE: 3 OF 3.

SURFACE INVOLVEMENT: PRESENT.

FALLOPIAN TUBE: POSITIVE FOR ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 812d1b69-df6c-4bb8-95a4-66b58880388b (TCGA-29-1697.294BA09F-347A-4129-847D-211CDF73CA99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).